Gene-level copy-number profile of tumor specimen TCGA-CN-6020-01A from TCGA case TCGA-CN-6020, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 58.1 years (21,232 days).
Specimen TCGA-CN-6020-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.f13b782a-bc92-4157-a743-916d1282cb12.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6020-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cce780df-e1c5-40e0-b8cb-5d418c8a5bbb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 819; copy number 2: 13,480; copy number 3: 27,401; copy number 4: 14,523; copy number 5: 1,661; copy number 6: 1,589; copy number 7: 34; copy number 9: 6; copy number 10: 14; copy number 13: 170; copy number 15: 35; copy number 16: 5; copy number 20: 46; copy number 30: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6020-01A-11D-1682-01): tumor purity 0.34, ploidy 2.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:79,092,848–79,193,160, 2 genes: AP002957.1, AP001547.1.
- chr13:101,717,564–101,802,488, 3 genes: AL160153.1, RNU1-24P, HMGB3P7.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 338 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,607–796,781, 17 genes, copy number 7 (within-gene range 4–7): AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1.
- chr6:60,281,444–60,942,327, 6 genes, copy number 9 (within-gene range 4–9): AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3.
- chr7:38,256,337–38,300,322, 8 genes, copy number 10: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr8:35,235,475–35,796,550, 1 gene, copy number 10 (within-gene range 2–10): UNC5D.
- chr8:35,525,176–35,707,734, 2 genes, copy number 10: LSM12P1, AC105230.1.
- chr8:38,142,700–39,730,065, 39 genes, copy number 7–13: STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18.
- chr11:69,737,298–75,669,120, 217 genes, copy number 13–30 (broad region; genes not listed).
- chr11:100,641,975–102,966,628, 48 genes, copy number 10–20: RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3.

Autosomal genes at a single copy (total copy number 1): 809. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
